Gene-level copy-number profile of tumor specimen TCGA-D3-A1Q5-06A from TCGA case TCGA-D3-A1Q5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 67.5 years (24,638 days).
Specimen TCGA-D3-A1Q5-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.09dfff19-3124-42cd-a3de-ef49b1760a1a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A1Q5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7ffccb37-089d-49e5-a5df-17369cf32d98

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 310; copy number 2: 18,527; copy number 3: 29,040; copy number 4: 11,773; copy number 7: 54; copy number 8: 5; copy number 14: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A1Q5-06A-11D-A194-01): tumor purity 0.92, ploidy 2.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,705,338–26,644,595, 97 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:44,793,119–45,076,066, 11 genes, copy number 14 (within-gene range 1–24): TMEM72-AS1, EIF2AP4, AL353801.2, TMEM72, AL353801.1, AL353801.3, RASSF4, DEPP1, ZNF22-AS1, ZNF22, CEP164P1.
- chr10:45,454,585–45,700,532, 3 genes, copy number 8 (within-gene range 1–8): MARCHF8, ZFAND4, AGAP10P.
- chr10:46,286,345–48,119,455, 54 genes, copy number 7 (within-gene range 1–7): ANTXRL, AGAP14P, FAM25BP, AC244230.1, ANXA8L1, AC244230.2, LINC00842, HNRNPA1P33, NPY4R, GPRIN2, SYT15, AL356056.2, AL356056.1, SHLD2P1, LINC02637, RHEBP1, RN7SL248P, FAM245B, CTSLP3, GLUD1P2, AL731733.1, BMS1P1, RNA5SP311, AGAP13P, FRMPD2B, PTPN20, GDF10, GDF2, RBP3, ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675, SHLD2P3, RN7SL453P, RHEBP2, FO681492.1, AC245041.2, NPY4R2, AC245041.1, FAM25C, AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr10:56,357,227–56,364,714, 2 genes, copy number 8: ZWINT, AC010996.1.

Autosomal genes at a single copy (total copy number 1): 310. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
